Somatic mutation profile of tumor specimen C3L-01287-02 (aliquot CPT0079410009) from CPTAC case C3L-01287, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 60.4 years (22,045 days).
Specimen C3L-01287-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8f8be44-a66c-4413-a497-8e1dc7671865.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01287-31 (Blood Derived Normal), aliquot CPT0080130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ce96218-c42c-4165-adc9-38fb56be09fd

The open-access MAF lists 65 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 17, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, Splice Site 2, Splice Region 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375129361, CM134949, COSV56236966; ClinVar: pathogenic; called by muse, mutect2
- CACNA1H | c.5384G>C p.G1795A | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52357665; called by muse, mutect2, varscan2
- CDH16 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751244459, COSV100233742; called by muse, mutect2, varscan2
- CDH23 | c.8674C>T p.R2892W | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1468886300, COSV56482903, COSV99819181; called by muse, mutect2, varscan2
- EIF2D | c.948+2T>C p.X316_splice | Splice Site (SNP) | VAF 24/108 reads (22%) | catalogued as rs1553411032; called by muse, mutect2, varscan2
- F13A1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs768408371, COSV53568965; called by muse, mutect2
- FAHD2A | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 42/428 reads (10%) | catalogued as rs773693722; called by muse, mutect2
- FKBP10 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 52/527 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as rs782380098; called by muse, mutect2, varscan2
- GRN | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 35/199 reads (18%) | catalogued as CM100886; called by muse, mutect2, varscan2
- JCAD | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64759879; called by muse, mutect2, varscan2
- OR5AS1 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100546397; called by muse, mutect2
- PDE2A | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV57809356; called by muse, mutect2
- PXDNL | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62477807; called by muse, mutect2, varscan2
- TENM1 | c.3967G>C p.D1323H | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64443876; called by muse, mutect2, varscan2
- TENT5D | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57638844; called by muse, mutect2, varscan2
- TMEM63C | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100029889; called by muse, mutect2
- TUBGCP2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs761200870; called by muse, mutect2, varscan2
- USP6NL | c.2483T>A p.L828Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs562437933; called by muse, varscan2
- ZNF526 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 37/686 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs147052277; called by muse, mutect2
- ACO1 | c.2423T>G p.L808R | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY9 | c.3617T>C p.I1206T | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ALKBH7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GALT5 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTNAP4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); called by muse, mutect2
- COL14A1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- DCBLD1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DPYD | c.2506G>C p.A836P | Missense Mutation (SNP) | VAF 39/541 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM149B1 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- GABBR2 | c.2197_2205del p.T733_T735del | In Frame Del (DEL) | VAF 68/313 reads (22%) | called by mutect2, pindel, varscan2
- HMCN1 | c.2211A>G p.K737= | Splice Region (SNP) | VAF 23/504 reads (5%) | called by muse, mutect2
- ILF2 | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 57/347 reads (16%) | called by muse, mutect2, varscan2
- KARS1 | c.1547_1551+1del p.X516_splice | Splice Site (DEL) | VAF 140/600 reads (23%) | called by pindel, varscan2*
- KIF1B | c.1402C>T p.P468S (on ENST00000377086 / NM_001365952.1; = p.P422S on NM_015074.3) | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- LUZP4 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MED1 | c.1400_1401dup p.D468Wfs*9 | Frame Shift Ins (INS) | VAF 62/420 reads (15%) | called by mutect2, pindel, varscan2
- NAV3 | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- RC3H1 | c.2490del p.D831Mfs*10 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | called by mutect2, pindel, varscan2
- RNF17 | c.1620C>A p.H540Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2
- SPEM2 | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM270 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- VHL | c.420_442del p.N141Cfs*25 | Frame Shift Del (DEL) | VAF 106/510 reads (21%) | called by mutect2, pindel
- ZNF219 | c.724_725del p.V243Pfs*12 | Frame Shift Del (DEL) | VAF 12/159 reads (8%) | called by mutect2, pindel*
- CACNA1H | c.5385C>T p.G1795= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as rs777171977; called by muse, mutect2, varscan2
- COG5 | c.2100A>T p.S700= (on ENST00000347053 / NM_001379512.1; = p.S721= on NM_006348.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 53/425 reads (12%) | called by muse, mutect2, varscan2
- CREBBP | c.1911A>G p.E637= | Silent (SNP) | VAF 33/727 reads (5%) | catalogued as COSV52124745; called by muse, mutect2
- FBLN2 | c.2691G>A p.R897= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1464459092; called by muse, mutect2
- HLA-DMB | c.93G>A p.L31= | Silent (SNP) | VAF 21/73 reads (29%) | called by muse, varscan2
- KDM2B | c.1563G>A p.V521= | Silent (SNP) | VAF 60/495 reads (12%) | called by muse, mutect2, varscan2
- KDM5A | c.2100C>G p.L700= | Silent (SNP) | VAF 71/409 reads (17%) | called by muse, mutect2, varscan2
- MBD5 | c.3753A>G p.P1251= | Silent (SNP) | VAF 43/330 reads (13%) | called by muse, mutect2, varscan2
- NOD2 | c.381G>A p.S127= | Silent (SNP) | VAF 37/230 reads (16%) | catalogued as rs535978538; called by muse, mutect2, varscan2
- NOTCH2 | c.6909C>T p.P2303= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs1311553574; called by muse, mutect2, varscan2
- PCDHB3 | c.1347C>T p.P449= | Silent (SNP) | VAF 142/883 reads (16%) | catalogued as rs782743177, COSV50569020, COSV50574942; called by muse, mutect2, varscan2
- PIWIL2 | c.2104C>A p.R702= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV63254478; called by muse, varscan2
- PTPRZ1 | c.1605A>C p.S535= | Silent (SNP) | VAF 45/308 reads (15%) | called by muse, mutect2, varscan2
- RIN1 | c.390C>T p.S130= | Silent (SNP) | VAF 54/364 reads (15%) | called by muse, mutect2, varscan2
- STYXL2 | c.1302G>T p.L434= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- TNNT3 | c.654G>A p.L218= (on ENST00000397301 / NM_001367846.1; = p.L207= on NM_006757.4) | Silent (SNP) | VAF 80/820 reads (10%) | called by muse, mutect2
- TRIM27 | c.1098C>T p.F366= | Silent (SNP) | VAF 51/292 reads (17%) | catalogued as rs1252217990, COSV65874203; called by muse, mutect2, varscan2
- FANCL | c.775+21A>G | Intron (SNP) | VAF 41/329 reads (12%) | called by muse, mutect2, varscan2
- LRP5L | n.298C>T | RNA (SNP) | VAF 70/402 reads (17%) | called by muse, mutect2, varscan2
- MBD2 | c.542+1616C>A | Intron (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- SREBF2 | c.2739-38A>G | Intron (SNP) | VAF 55/351 reads (16%) | catalogued as rs746778890; called by muse, mutect2, varscan2
- SUN2 | c.-102-10C>A | Intron (SNP) | VAF 48/269 reads (18%) | called by mutect2, varscan2
- ZFPL1 | chr11:65090494 T>G | 3'Flank (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
